FM case AD3584 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas; Primary site: Eye and adnexa.
https://portal.gdc.cancer.gov/cases/2d38d834-ef7a-477c-bf14-7c0954d2b973

Male, 48.1 years: Melanoma, NOS (ICD-O-3 8720/3) of the eye; primary biopsied or resected from the eye. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
